Surgical pathology report (de-identified scan), TCGA case TCGA-61-1727, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1727-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1, PART 2 AND

PART 3: OVARY AND FALLOPIAN TUBE, RIGHT SALPINGO-OOPHORECTOMY AND FROZEN SECTIONS –

- A. OVARY WITH POORLY-DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA WITH HEMORRHAGIC ISCHEMIC NECROSIS. (see comment)
- B. FALLOPIAN TUBE WITH METASTATIC ADENOCARCINOMA INVOLVING MESOSALPINX.

PART 4: OVARY AND FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY –

- A. OVARY WITH SEROUS CYSTADENOFIBROMA, EPITHELIAL INCLUSIONS AND HEMORRHAGIC SEROSAL ADHESIONS, NO TUMOR SEEN.
- B. FALLOPIAN TUBE WITH PARATUBAL CYST, NO TUMOR SEEN.

PART 5: APPENDIX, APPENDECTOMY –

VERMIFORM APPENDIX WITH HEMORRHAGIC SEROSAL ADHESIONS AND ACUTE INFLAMMATION, NO TUMOR SEEN.

PART 6: SMALL INTESTINE, PORTION OF ILIUM, RESECTION AND FROZEN SECTION –

- A. PORTION OF SMALL INTESTINE WITH SEROSAL MICROSCOPIC FOCI OF METASTATIC ADENOCARCINOMA (6C, 6D, 6E and 6FS) AND ORGANIZED HEMATOMA WITH EXTENSIVE HEMORRHAGIC SEROSAL ADHESIONS WITH ACUTE AND CHRONIC INFLAMMATION, HEMOSIDERIN-LADEN MACROPHAGES, MESOTHELIAL PROLIFERATION AND DYSTROPHIC CALCIFICATIONS.
- B. MARGINS OF RESECTION WITH ACUTE SEROSITIS AND HEMORRHAGIC ADHESIONS, NO TUMOR SEEN.

PART 7: OMENTUM, BIOPSY –

- A. OMENTUM WITH ORGANIZED HEMATOMA, INFLAMMATION WITH ATYPICAL REACTIVE MESOTHELIAL PROLIFERATION AND GRANULATION TISSUE WITH HEMORRHAGIC ADHESIONS.
- B. NO TUMOR SEEN.

COMMENT:

The peritoneal cytology

is positive for malignant cells, metastatic adenocarcinoma.

Immunohistochemical staining results for P53, WT-1, estrogen receptor, vimentin and P16, support the diagnosis of papillary serous adenocarcinoma (see microscopic description).

CASE SYNOPSIS:

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Right
PROCEDURE:	Bilateral Salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 9 cm
TUMOR TYPE:	Papillary serous carcinoma
HISTOLOGIC SILVERBERG GRADE:	Poorly differentiated (8-9 pts)
ARCHITECTURAL PATTERN:	Solid (3)
CYTOLOGIC ATYPIA:	Marked (3)
MITOTIC COUNTS / 10hpf:	> or = 25 (3)
VASCULAR INVASION:	No
TUMOR CAPSULE:	Ruptured
SURFACE IMPLANTS:	Invasive
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	Yes
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 0
T STAGE, PATHOLOGIC:	pT1c
N STAGE, PATHOLOGIC:	pNX
M STAGE, PATHOLOGIC:	pMX
FIGO STAGE:	IC

Source: NCI Genomic Data Commons file 743d6edc-6414-4821-b405-30fbabd81cc6 (TCGA-61-1727.F8E2CBF2-911A-48A7-AD80-C23124AF44FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).